Gene-level copy-number profile of tumor specimen TCGA-51-4079-01A from TCGA case TCGA-51-4079, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.6 years (26,899 days).
Specimen TCGA-51-4079-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.9a8ff65f-67c1-48cc-a712-71a704da452a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-51-4079-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4e87977-c5a7-4f83-b2da-59935bbc6b20

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,079; copy number 2: 14,941; copy number 3: 5,613; copy number 4: 32,486; copy number 5: 112; copy number 6: 2,669; copy number 7: 1,554; copy number 8: 698; copy number 9: 371; copy number 10: 3; copy number 11: 82; copy number 12: 65; copy number 13: 2; copy number 14: 107; copy number 23: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-51-4079-01A-01D-1097-01): tumor purity 0.62, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 660 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:56,750,300–63,827,843, 109 genes, copy number 9–23 (within-gene range 6–23) (broad region; genes not listed).
- chr2:66,235,377–67,684,077, 20 genes, copy number 9 (within-gene range 4–9): AC118345.1, AC092669.1, MIR4778, LINC01873, MEIS1-AS3, MEIS1, MEIS1-AS2, LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1.
- chr3:99,817,837–106,427,977, 63 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr3:106,515,897–106,515,998, 1 gene, copy number 11: Y_RNA.
- chr3:145,523,538–163,361,563, 293 genes, copy number 9–10 (broad region; genes not listed).
- chr5:18,547,312–18,746,173, 2 genes, copy number 9: RN7SL58P, LINC02100.
- chr5:94,111,720–97,882,687, 65 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).
- chr18:21,182,503–26,391,685, 107 genes, copy number 14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
